Somatic mutation profile of tumor specimen 0DU81D from CCDI case PBCJIV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.6 years (2,036 days).
Specimen 0DU81D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 939fcffc-08cd-42a4-8638-e4a8298139b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU9N9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7019103-cdcb-47d4-a4bf-9c71e14ca41c

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 2, Silent 2, Frame Shift Del 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 109/677 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs387906589, CM091421, COSV55115990, COSV55115998; ClinVar: likely pathogenic / other; called by muse, mutect2, varscan2
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 111/479 reads (23%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 158/687 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DRP2 | c.1258C>G p.L420V | Missense Mutation (SNP) | VAF 62/666 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as COSV100871992; called by muse, mutect2
- RSPH10B | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 54/539 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.078); catalogued as rs749914563; called by muse, mutect2, varscan2
- STPG1 | c.49C>T p.R17C (on ENST00000337248 / NM_001199013.2; = p.D9= on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/619 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.183); catalogued as rs1352560339, COSV99134575; called by muse, mutect2
- FATE1 | c.234+1G>T p.X78_splice | Splice Site (SNP) | VAF 22/568 reads (4%) | called by muse, mutect2
- LRRC66 | c.509_510del p.L170Qfs*20 | Frame Shift Del (DEL) | VAF 37/267 reads (14%) | called by mutect2, varscan2
- OR10T2 | c.269C>T p.T90I | Missense Mutation (SNP) | VAF 28/906 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.009); called by muse, mutect2
- COBLL1 | c.2937G>A p.E979= (on ENST00000392717; = p.E941= on NM_014900.5) | Silent (SNP) | VAF 108/692 reads (16%) | called by muse, mutect2
- OR10X1 | c.264C>T p.C88= | Silent (SNP) | VAF 65/555 reads (12%) | called by muse, mutect2, varscan2
- C1orf162 | c.107+89G>T | Intron (SNP) | VAF 11/253 reads (4%) | called by muse, mutect2
- TMEM268 | c.-8G>A | 5'UTR (SNP) | VAF 15/121 reads (12%) | catalogued as rs757518784, COSV55986924; called by mutect2, varscan2
- UGT1A6 | c.862-23316G>A | Intron (SNP) | VAF 118/906 reads (13%) | catalogued as rs751411472, COSV59385787; called by muse, mutect2, varscan2
